Gene-level copy-number profile of tumor specimen MP2PRT-PAVWUF-TMP1-A from MP2PRT case MP2PRT-PAVWUF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,576 days).
Specimen MP2PRT-PAVWUF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c3a0ae94-f5dd-4c3f-917c-edef60466988.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVWUF-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/3c186faa-f1dd-4c86-93e5-958332d4b2a7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 538; copy number 1: 3,645; copy number 2: 54,558; copy number 3: 162.

Homozygous deletions (total copy number 0; autosomes only): 486 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:62,196,115–62,350,739, 4 genes: B3GNT2, MIR5192, RN7SL51P, AC093159.2.
- chr2:87,311,460–87,459,044, 4 genes (within-gene range 0–2): AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943.
- chr2:88,857,161–89,245,596, 38 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr5:98,929,171–98,995,013, 3 genes: LINC02062, Y_RNA, AC022121.1.
- chr6:156,350,579–156,505,011, 3 genes: AL512658.2, SNORD28B, AL512658.1.
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–1): TRGC1.
- chr7:38,276,259–38,311,808, 5 genes (within-gene range 0–1): TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,438,547–22,536,204, 62 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,715,181, 168 genes (within-gene range 0–2) (broad region; genes not listed).
- chr19:1,177,558–4,269,088, 176 genes (broad region; genes not listed).
- chr22:22,030,934–22,162,681, 19 genes (within-gene range 0–2): IGLV4-69, IGLVI-68, AC245452.4, AC245452.3, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60.
- chr22:28,800,683–28,848,559, 3 genes (within-gene range 0–2): Z93930.2, Z93930.3, Z93930.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
